Surgical pathology report (de-identified scan), TCGA case TCGA-N5-A4RV, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site MSKCC, specimen TCGA-N5-A4RV-01A (Primary Tumor).

[page 1 of 3]
Carcinosarcoma / Mixed Mullerian
Tumor, malignant 8950/3

Site C&CF Uterus, NOS C55.9
path Endometrium C54.1

JW 4/2/13

Specimens Submitted:

- 1: SP: Uterus, cervix, bilateral tubes and ovaries
- 2: SP: Right para-aortic nodes
- 3: SP: Left para-aortic nodes
- 4: SP: Right external iliac lymph nodes
- 5: SP: Right obturator lymph nodes
- 6: SP: Left external iliac lymph nodes
- 7: SP: Left obturator lymph nodes
- 8: SP: Omentum

DIAGNOSIS:

1) UTERUS, CERVIX, FALLOPIAN TUBES AND OVARIES: TOTAL HYSTERECTOMY
AND BILATERAL SALPINGO-OOPHORECTOMY:
- CARCINOSARCOMA OF ENDOMETRIUM (MALIGNANT MIXED MULLERIAN TUMOR), SEE
NOTE.

- NO MYOMETRIAL INVASION IS IDENTIFIED.
- NO ENDOCERVICAL INVASION IS IDENTIFIED.
- NO DEFINITE VASCULAR INVASION IS IDENTIFIED.
- THE CERVIX IS UNREMARKABLE.
- THE ENDOMETRIUM SHOWS THE FOLLOWING ABNORMALITY: ATROPHY.
- THE MYOMETRIUM IS UNREMARKABLE.
- THE RIGHT OVARY SHOWS INCLUSION CYST.
- THE LEFT OVARY SHOWS INCLUSION CYST.
- THE FALLOPIAN TUBES ARE UNREMARKABLE.

NOTE: THE SARCOMATOUS COMPONENT HAS A HOMOLOGOUS APPEARANCE OVERALL, BUT
IMMUNOHISTOCHEMICAL STAINS ARE BEING PERFORMED TO PROVIDE SUPPORT FOR A
FOCAL RHABDOMYOBlastic COMPONENT. THE RESULTS WILL BE REPORTED IN AN
ADDENDUM.

- 2) LYMPH NODE, RIGHT PARA-AORTIC; EXCISION:
- FIVE BENIGN LYMPH NODES (0/5).
- 3) LYMPH NODE, LEFT PARA-AORTIC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).

** Continued on next page **

[page 2 of 3]
-
- 4) LYMPH NODE, RIGHT EXTERNAL ILIAC; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 5) LYMPH NODE, RIGHT OBTURATOR; EXCISION:
- FIVE BENIGN LYMPH NODES (0/5).
- 6) LYMPH NODE, LEFT EXTERNAL ILIAC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- 7) LYMPH NODE, LEFT OBTURATOR; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 8) OMENTUM; OMENTECTOMY:
- OMENTUM NEGATIVE FOR TUMOR.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

[page 3 of 3]
Procedures/Addenda:
Addendum

Addendum Diagnosis

IMMUNOHISTOCHEMICALLY, THE TUMOR IS NEGATIVE FOR MYOGENIN AND MYO D-1.
THERE IS THEREFORE NO IMMUNOHISTOCHEMICAL SUPPORT FOR HETEROLOGOUS
RHABDOMYBLASTIC DIFFERENTIATION.

** End of Report **

LN 12/31/12		Yes	No
1	Discrepancy		✓
2			✓
3			✓
4			✓
5			✓
6			✓
7			✓
8			✓
9			✓
10			✓
11			✓
12			✓
13			✓
14			✓
15			✓
16			✓
17			✓
18			✓
19			✓
20			✓
21			✓
22			✓
23			✓
24			✓
25			✓
26			✓
27			✓
28			✓
29			✓
30			✓
31			✓
32			✓
33			✓
34			✓
35			✓
36			✓
37			✓
38			✓
39			✓
40			✓
41			✓
42			✓
43			✓
44			✓
45			✓
46			✓
47			✓
48			✓
49			✓
50			✓
51			✓
52			✓
53			✓
54			✓
55			✓
56			✓
57			✓
58			✓
59			✓
60			✓
61			✓
62			✓
63			✓
64			✓
65			✓
66			✓
67			✓
68			✓
69			✓
70			✓
71			✓
72			✓
73			✓
74			✓
75			✓
76			✓
77			✓
78			✓
79			✓
80			✓
81			✓
82			✓
83			✓
84			✓
85			✓
86			✓
87			✓
88			✓
89			✓
90			✓
91			✓
92			✓
93			✓
94			✓
95			✓
96			✓
97			✓
98			✓
99			✓
100			✓

Source: NCI Genomic Data Commons file a0543232-59a0-42ca-8fe3-47d23d536847 (TCGA-N5-A4RV.A03181A9-52A0-4326-8E75-137D8E874307.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).